Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAD0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAD0-01A (Primary Tumor).

[page 1 of 2]
LINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen:

Liver: 17.0 x 11.5 x 7.5 cm, 419.0 gm (fresh)

Operation: Left lateral hepatectomy

Lesion: A relatively well-defined, buldging mass (13.0 x 7.5 x 6.5 cm)

Cut surface: Bile-tinged, ovoid, solid, granular with necrosis

Gross type: Expanding nodular

Resection margin: Not involved grossly (safety margin: 0.2 cm)

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4 and TB, bile tinged mass and surrounding liver parenchyme x 5

L and NB, nontumorous liver parenchyme x 2

RM, resection margin of liver x 1

MICROSCOPIC:

Hepatocellular carcinoma:

The worst differentiation II

The major differentiation II

Histologic type: Trabecular and pseudoglandular

Cell type: Hepatic

Fatty change: Yes (30 %)

Cholangiocarcinoma: No

Combined hepatocellular and cholangiocarcinoma: No

Fibrous capsule formation: Partial capsule

Capsular infiltration: Yes

Septum formation: Yes

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: No

Multicentric occurrence: No

Non-tumor liver pathology

1. Chronic hepatitis: Yes

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

JA 5/19/14

[page 2 of 2]
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: Minimal
- 1-3. Grade, portoperiportal: Mild
- 1-4. Stage (fibrosis): Cirrhosis
- 1-5. Cirrhosis: Mixed
2. Dysplastic nodule: No
3. Ductal epithelial dysplasia: No
4. Other liver diseases: No

NOT reported. Gross:

Peritoneal fluid, smear, suggestive of, malignancy

Liver, left, ectomy, Hepatocellular carcinoma
T56000, left, P10, M81703

DIAGNOSIS:

Liver, left, lateral hepatectomy: Hepatocellular carcinoma

Suggestion :

Source: NCI Genomic Data Commons file 860b72b7-fb64-4831-9491-6d76e3b48321 (TCGA-DD-AAD0.7A0FAFC9-DB9A-4648-8184-D0A03EFCF16D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).